Somatic mutation profile of tumor specimen TCGA-35-4123-01A (aliquot TCGA-35-4123-01A-01D-1105-08) from TCGA case TCGA-35-4123, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 38.5 years (14,064 days).
Specimen TCGA-35-4123-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e374a19-87e1-41ed-9dd7-9fd2e653c13a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-35-4123-10A (Blood Derived Normal), aliquot TCGA-35-4123-10A-01D-1105-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15a1e41c-d1b4-435d-816e-930c8731998e

The open-access MAF lists 310 somatic variants for this specimen: 223 protein-altering or splice-affecting, 82 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 192, Silent 82, Nonsense Mutation 17, Splice Site 7, Frame Shift Ins 3, Frame Shift Del 3, Intron 2, RNA 2, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF4 | c.296G>A p.C99Y | Missense Mutation (SNP) | VAF 34/260 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705766; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 83/253 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- RYR1 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 47/299 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057518970, COSV62104015; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 38/129 reads (29%) | hotspot (GDC flag); catalogued as rs1131691026, CM101750, COSV52661500, COSV52987374, COSV53571745; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM33 | c.521C>A p.T174N | Missense Mutation (SNP) | VAF 70/356 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.115); catalogued as COSV62935931; called by muse, mutect2, varscan2
- ADAMTS18 | c.2782G>T p.A928S | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV51400765, COSV51419823; called by muse, mutect2, varscan2
- AGR3 | c.420G>T p.L140F | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.816); catalogued as COSV60038866; called by muse, mutect2, varscan2
- AMER3 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.156); catalogued as COSV58468465; called by muse, mutect2, varscan2
- ANGPTL2 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 78/346 reads (23%) | catalogued as rs375360881; called by muse, varscan2
- ANKRD53 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as COSV55538289; called by muse, mutect2
- ANO4 | c.1079T>A p.M360K (on ENST00000392977 / NM_001286615.2; = p.M325K on NM_178826.4) | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1244622223, COSV54605314; called by muse, mutect2, varscan2
- ARL16 | c.38C>A p.A13D | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs774636076, COSV100230290, COSV61270642; called by muse, mutect2, varscan2
- ARSF | c.453C>A p.C151* | Nonsense Mutation (SNP) | VAF 27/74 reads (36%) | catalogued as COSV63840392; called by muse, mutect2, varscan2
- ARSH | c.1253C>A p.S418Y | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66963549; called by muse, mutect2, varscan2
- BCOR | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV100652993; called by muse, mutect2, varscan2
- BEST3 | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV56995349; called by muse, mutect2, varscan2
- BRF1 | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 84/290 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as rs587763042, COSV100526908; called by muse, mutect2, varscan2
- BTBD11 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 29/158 reads (18%) | catalogued as COSV55031141; called by muse, mutect2, varscan2
- C12orf40 | c.980T>A p.M327K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV100209717; called by muse, mutect2
- C1orf94 | c.740C>A p.S247Y (on ENST00000488417 / NM_001134734.2; = p.S57Y on NM_032884.5) | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.178); catalogued as rs992466684, COSV64914752; called by muse, mutect2, varscan2
- C5orf34 | c.32A>G p.E11G | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.238); catalogued as COSV60931314; called by muse, mutect2, varscan2
- CACNA1D | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as rs533046755, COSV55456930, COSV55467087; called by muse, mutect2, varscan2
- CACNA1G | c.4079A>G p.D1360G | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61732838, COSV61742462; called by muse, mutect2
- CAD | c.6322A>C p.S2108R | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as COSV53029523; called by muse, mutect2, varscan2
- CCT8L2 | c.764C>A p.A255E | Missense Mutation (SNP) | VAF 60/256 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as COSV63463243; called by muse, mutect2, varscan2
- CD163L1 | c.2301G>T p.W767C | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58020753; called by muse, mutect2, varscan2
- CDC14A | c.1466A>G p.N489S | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV60560929; called by muse, mutect2
- CDH17 | c.416C>A p.S139Y | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as COSV50333880; called by muse, mutect2, varscan2
- CEP135 | c.2746A>T p.T916S | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.59); catalogued as COSV57261607; called by muse, mutect2, varscan2
- CETN2 | c.291+1G>T p.X97_splice | Splice Site (SNP) | VAF 40/115 reads (35%) | catalogued as COSV64744700; called by muse, mutect2, varscan2
- CETN2 | c.291G>T p.M97I | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.159); catalogued as COSV64743916, COSV64744703; called by muse, mutect2, varscan2
- CFAP61 | c.1797G>T p.K599N | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.647); catalogued as COSV55639090; called by muse, mutect2, varscan2
- CHRM2 | c.1018A>C p.T340P | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV57770184, COSV57778914; called by muse, mutect2
- CHST10 | c.534-1G>T p.X178_splice | Splice Site (SNP) | VAF 31/110 reads (28%) | catalogued as rs1438247171, COSV99958727; called by muse, mutect2, varscan2
- CHUK | c.201-1G>T p.X67_splice | Splice Site (SNP) | VAF 22/101 reads (22%) | catalogued as COSV64917663, COSV64918404; called by muse, mutect2, varscan2
- CIITA | c.3197G>T p.R1066L | Missense Mutation (SNP) | VAF 74/422 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV60859939; called by mutect2, varscan2
- CNTF | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100284360; called by muse, mutect2, varscan2
- CNTNAP4 | c.3259G>T p.E1087* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV56684146; called by muse, mutect2, varscan2
- CNTNAP5 | c.1343G>T p.G448V | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70498912; called by muse, mutect2, varscan2
- COL15A1 | c.2668C>T p.P890S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.793); catalogued as COSV100898042, COSV66643479; called by muse, mutect2, varscan2
- CPNE4 | c.900C>G p.I300M | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV70197377; called by muse, mutect2, varscan2
- CSMD2 | c.9754G>T p.G3252W | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV53899029, COSV53936910; called by muse, mutect2, varscan2
- CSTF2T | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as COSV58657104, COSV58657270; called by muse, mutect2, varscan2
- CUBN | c.10837C>A p.R3613S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV64722089; called by muse, mutect2, varscan2
- CYP4F3 | c.1314G>A p.E438= | Splice Region (SNP) | VAF 76/424 reads (18%) | catalogued as COSV55411897; called by muse, mutect2, varscan2
- DBH | c.104C>A p.A35D | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV55041784; called by muse, mutect2
- DDO | c.898G>T p.V300L (on ENST00000368924 / NM_001368172.1; = p.V241L on NM_004032.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as COSV64470336; called by muse, mutect2, varscan2
- DMBX1 | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100760679, COSV63601770; called by muse, mutect2, varscan2
- DNAH5 | c.2957A>T p.H986L | Missense Mutation (SNP) | VAF 28/244 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV54240348; called by muse, varscan2
- DPH1 | c.189G>T p.R63S | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV53985677; called by muse, mutect2, varscan2
- DSG4 | c.1240A>G p.I414V | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs775595162, COSV57394679; called by muse, mutect2, varscan2
- ENSA | c.14A>G p.Q5R | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV99651225; called by muse, mutect2, varscan2
- EPC2 | c.2063G>T p.S688I | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as COSV51546974, COSV51548360; called by muse, mutect2, varscan2
- EPS8L3 | c.1741C>T p.R581W (on ENST00000361965 / NM_133181.4; = p.R551W on NM_024526.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs554030593, COSV62608734; called by muse, mutect2, varscan2
- ERICH3 | c.1571A>G p.N524S | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.586); catalogued as rs753986445, COSV58612971; called by muse, mutect2, varscan2
- EXOC3 | c.1192G>C p.A398P | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV59267870; called by muse, mutect2, varscan2
- EYS | c.218C>A p.A73D | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1326141824, COSV60993825; called by muse, mutect2, varscan2
- FAM160A2 | c.1391A>T p.H464L | Missense Mutation (SNP) | VAF 62/378 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV56413169; called by muse, mutect2, varscan2
- FBXO10 | c.2534A>T p.H845L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV52834413; called by muse, mutect2, varscan2
- FLT1 | c.814-2A>G p.X272_splice | Splice Site (SNP) | VAF 5/30 reads (17%) | catalogued as COSV56735050; called by muse, mutect2, varscan2
- FREM1 | c.526G>T p.D176Y | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.423); catalogued as COSV101083944; called by muse, mutect2, varscan2
- FRMPD1 | c.1021A>G p.I341V | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.509); catalogued as COSV66701522; called by muse, mutect2
- FTCD | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.581); catalogued as rs752941882, COSV52427376; called by muse, mutect2, varscan2
- GABRA2 | c.61G>T p.D21Y | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.041); catalogued as COSV62915075; called by muse, mutect2, varscan2
- GALNT17 | c.524C>A p.A175D | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100356616, COSV61176680; called by muse, mutect2, varscan2
- GOLGB1 | c.7114A>T p.R2372W | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV61468454; called by muse, mutect2, varscan2
- GORAB | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV63026499; called by muse, mutect2, varscan2
- GPA33 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1253823064, COSV63301211, COSV63301710; called by muse, mutect2, varscan2
- GPR50 | c.465G>T p.M155I | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV54438397, COSV54443109; called by muse, mutect2, varscan2
- GRIA3 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52072088; called by muse, mutect2, varscan2
- GRIN2A | c.926A>C p.K309T | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV58046640; called by mutect2, varscan2
- GRM7 | c.1942G>A p.A648T | Missense Mutation (SNP) | VAF 15/241 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV63156270; called by muse, mutect2
- GUCY1A2 | c.1153C>T p.P385S | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as rs867033183, COSV56494505; called by muse, mutect2, varscan2
- HAL | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 168/782 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs747932603, COSV54118376; called by muse, mutect2, varscan2
- HAVCR1 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59401726; called by muse, mutect2, varscan2
- HDAC9 | c.1591A>T p.S531C | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV67779651; called by muse, mutect2, varscan2
- IL10RA | c.537+1G>C p.X179_splice | Splice Site (SNP) | VAF 26/118 reads (22%) | catalogued as COSV57141517; called by muse, mutect2, varscan2
- INSC | c.569G>C p.C190S | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65412010; called by muse, mutect2, varscan2
- INTU | c.2820A>T p.L940F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV58873361; called by muse, mutect2, varscan2
- ITCH | c.405G>T p.L135F | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV52934588; called by muse, mutect2, varscan2
- JAKMIP1 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 100/514 reads (19%) | catalogued as COSV51533007, COSV51538810; called by muse, varscan2
- JMJD1C | c.6822G>T p.M2274I | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100550199; called by muse, varscan2
- JMJD1C | c.6005C>T p.P2002L | Missense Mutation (SNP) | VAF 64/399 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs768539248, COSV59516869; called by muse, mutect2, varscan2
- KCNB1 | c.2083C>A p.L695I | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.028); catalogued as rs775433680, COSV65569835; called by muse, mutect2, varscan2
- KCNK10 | c.152T>A p.V51E | Missense Mutation (SNP) | VAF 38/283 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.772); catalogued as COSV56649041; called by muse, mutect2, varscan2
- KDM4C | c.2344G>C p.V782L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as COSV67189373; called by muse, mutect2, varscan2
- KLB | c.1577C>A p.S526Y | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV57303459; called by muse, mutect2, varscan2
- KRT1 | c.1615T>A p.Y539N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV52868123; called by muse, varscan2
- KRT82 | c.934C>A p.Q312K | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.74); catalogued as COSV57786688; called by muse, mutect2, varscan2
- LGALS13 | c.413G>T p.C138F | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV55680402; called by muse, mutect2, varscan2
- LIG3 | c.1423G>T p.A475S | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as COSV99252262; called by muse, mutect2, varscan2
- LMO7 | c.4753G>T p.G1585C (on ENST00000357063; = p.G1266C on NM_005358.5) | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58542623; called by muse, mutect2, varscan2
- LMTK2 | c.1270C>T p.Q424* | Nonsense Mutation (SNP) | VAF 33/97 reads (34%) | catalogued as COSV52000058; called by muse, mutect2, varscan2
- LRP1B | c.3944G>A p.G1315E | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67197543, COSV67250971; called by muse, mutect2, varscan2
- LRRC25 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.021); catalogued as COSV100170455; called by muse, mutect2, varscan2
- LRRIQ1 | c.4028A>T p.Q1343L | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67834975; called by muse, mutect2, varscan2
- LRRN2 | c.748G>T p.A250S | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.079); catalogued as COSV65784332; called by muse, mutect2, varscan2
- LRRN3 | c.1980C>A p.S660R | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57822121; called by muse, mutect2, varscan2
- LTBP1 | c.4624G>C p.G1542R (on ENST00000404816 / NM_206943.4; = p.G1216R on NM_000627.4) | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV55376866, COSV55382584, COSV55382653; called by muse, mutect2, varscan2
- MAP1LC3C | c.184C>T p.Q62* | Nonsense Mutation (SNP) | VAF 16/176 reads (9%) | catalogued as COSV61803903; called by muse, mutect2
- MFSD14A | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64514973; called by muse, mutect2, varscan2
- MMP13 | c.1133A>G p.E378G | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV52823604, COSV52824798; called by muse, mutect2
- MMP27 | c.7C>A p.R3S | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs558421984, COSV52780898, COSV52781818; called by muse, mutect2, varscan2
- MSH6 | c.3610G>C p.A1204P | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52284054; called by muse, mutect2, varscan2
- MTOR | c.3637A>G p.I1213V | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV63875294; called by muse, mutect2, varscan2
- MUC16 | c.33275C>A p.P11092H | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.937); catalogued as COSV67480153; called by muse, mutect2, varscan2
- MYEOV | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as COSV58294856; called by muse, mutect2, varscan2
- MYH1 | c.2312C>A p.A771D | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56853182; called by muse, mutect2
- MYO1G | c.2167G>T p.G723C | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51855987; called by muse, mutect2, varscan2
- MYOM2 | c.3098G>A p.R1033H | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776234545, COSV100036355, COSV50740642; called by muse, mutect2, varscan2
- NDEL1 | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.065); catalogued as COSV100232795; called by muse, mutect2, varscan2
- NPR3 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs760331365, COSV54090788; called by muse, mutect2, varscan2
- NRG3 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100932801, COSV64574651; called by muse, mutect2, varscan2
- NRXN2 | c.3848-2A>T p.X1283_splice | Splice Site (SNP) | VAF 4/21 reads (19%) | catalogued as COSV55459022; called by muse, mutect2
- NRXN2 | c.2752G>T p.D918Y | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV55451420, COSV55459041; called by muse, mutect2, varscan2
- NTF3 | c.324C>A p.D108E | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV58418008; called by muse, mutect2, varscan2
- OCA2 | c.2026A>G p.R676G | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62352304; called by muse, mutect2, varscan2
- OR13C2 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as rs77428321, COSV73377755; called by muse, mutect2, varscan2
- OR2L8 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs763873339, COSV61726091; called by muse, mutect2, varscan2
- OR2T33 | c.494C>A p.P165Q | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV100532328, COSV58816478; called by muse, mutect2, varscan2
- OR4A16 | c.515T>C p.I172T | Missense Mutation (SNP) | VAF 53/199 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV59044307; called by muse, mutect2, varscan2
- OR4K17 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59648658; called by muse, mutect2, varscan2
- OR52H1 | c.621G>T p.M207I (on ENST00000322653; = p.M213I on NM_001005289.1) | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.457); catalogued as COSV100497264; called by muse, mutect2, varscan2
- OR52I2 | c.181C>A p.L61M | Missense Mutation (SNP) | VAF 58/340 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV57045694; called by muse, mutect2, varscan2
- OR5AS1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs775842242, COSV57981863, COSV57983631; called by muse, mutect2
- OR6N2 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as COSV59412309, COSV59413557; called by muse, mutect2, varscan2
- OR8B8 | c.399G>T p.M133I | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV60145207; called by muse, mutect2, varscan2
- PADI6 | c.1678G>C p.E560Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.211); catalogued as COSV61885293; called by muse, varscan2
- PALD1 | c.511C>A p.L171M | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54976544; called by muse, mutect2, varscan2
- PCDH10 | c.2312G>C p.C771S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.977); catalogued as COSV52099553, COSV52101228; called by muse, mutect2
- PCDH17 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs769778384, COSV100931563, COSV64976726; called by muse, mutect2, varscan2
- PCDHB12 | c.2137C>A p.L713M | Missense Mutation (SNP) | VAF 155/394 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); catalogued as COSV53399067; called by muse, mutect2, varscan2
- PDE10A | c.1502C>G p.S501C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.048); catalogued as COSV63101986; called by muse, mutect2, varscan2
- PDE6C | c.515C>A p.T172N | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65116820; called by muse, mutect2, varscan2
- PDE6C | c.1123G>T p.G375* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as COSV65116825; called by muse, mutect2
- PDILT | c.1701G>T p.K567N | Missense Mutation (SNP) | VAF 75/300 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as COSV56703607; called by muse, mutect2, varscan2
- PDP1 | c.1471G>T p.E491* | Nonsense Mutation (SNP) | VAF 53/205 reads (26%) | catalogued as COSV99892030; called by muse, varscan2
- PDZRN3 | c.2626C>A p.H876N | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV55208906; called by muse, mutect2, varscan2
- PGR | c.615G>T p.W205C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); catalogued as COSV99677595, COSV99677628; called by muse, mutect2, varscan2
- PKHD1L1 | c.5323G>C p.V1775L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs1303031718, COSV65748078; called by muse, mutect2
- PKP2 | c.2322G>C p.L774F | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV50738809; called by muse, mutect2
- PLA2G3 | c.556C>A p.R186S | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV53211152; called by muse, mutect2, varscan2
- POLD2 | c.653T>G p.L218R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99788497; called by muse, mutect2, varscan2
- POTEE | c.2539C>A p.R847S | Missense Mutation (SNP) | VAF 156/636 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as COSV58237595; called by muse, varscan2
- PRAMEF2 | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 108/553 reads (20%) | catalogued as COSV53577498; called by muse, mutect2, varscan2
- PREX1 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as COSV64254545; called by muse, mutect2, varscan2
- PSG9 | c.837C>A p.S279R | Missense Mutation (SNP) | VAF 121/568 reads (21%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.982); catalogued as COSV52486662; called by muse, mutect2, varscan2
- PSMB6 | c.545C>A p.T182N | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV99566938; called by muse, mutect2
- PTCHD4 | c.2171T>A p.F724Y | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.993); catalogued as COSV59791315; called by muse, mutect2, varscan2
- R3HCC1L | c.1975G>T p.D659Y (on ENST00000612478 / NM_001256619.2; = p.D645Y on NM_014472.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54403545; called by muse, mutect2, varscan2
- RBM15 | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.076); catalogued as rs757723826, COSV63923938; called by muse, mutect2, varscan2
- RDH8 | c.892G>T p.V298L (on ENST00000651512; = p.V278L on NM_015725.4) | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as rs1315972397, COSV50676479; called by muse, mutect2, varscan2
- RDX | c.1226A>T p.D409V | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); catalogued as COSV58195476; called by muse, mutect2, varscan2
- RFX4 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57578486; called by muse, mutect2, varscan2
- SEC23IP | c.2599G>T p.G867* | Nonsense Mutation (SNP) | VAF 22/170 reads (13%) | catalogued as COSV64833343; called by muse, mutect2, varscan2
- SEMA3E | c.1720G>A p.G574R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100317607, COSV57089815, COSV57100301; called by muse, mutect2
- SERPINB3 | c.1012G>C p.E338Q | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52192764, COSV52192983; called by muse, mutect2, varscan2
- SERPINI2 | c.653C>A p.A218D | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.549); catalogued as COSV52987719; called by muse, mutect2, varscan2
- SETBP1 | c.884G>T p.S295I | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.173); catalogued as COSV56330038; called by muse, mutect2, varscan2
- SGCD | c.247G>T p.E83* (on ENST00000435422 / NM_001128209.2; = p.E84* on NM_000337.5) | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV61912491; called by muse, mutect2, varscan2
- SHOX2 | c.976G>A p.A326T (on ENST00000441443 / NM_006884.3; = p.A350T on NM_003030.4) | Missense Mutation (SNP) | VAF 52/1029 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs1476417389, COSV67464307; called by muse, mutect2
- SIRPG | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53808942; called by muse, mutect2, varscan2
- SLC11A2 | c.1690A>G p.M564V (on ENST00000394904 / NM_001379455.1; = p.M535V on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs767778859, COSV50373113; called by muse, mutect2, varscan2
- SLC22A6 | c.350C>A p.P117Q | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.706); catalogued as COSV64560633; called by muse, mutect2, varscan2
- SLC25A52 | c.52G>T p.E18* (on ENST00000672005; = p.E8* on NM_001034172.4) | Nonsense Mutation (SNP) | VAF 38/264 reads (14%) | catalogued as COSV52503393; called by muse, mutect2, varscan2
- SLC4A5 | c.3187C>A p.Q1063K | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.596); catalogued as COSV61030593; called by muse, mutect2, varscan2
- SLC6A14 | c.1034C>G p.S345C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV64146979, COSV64147891; called by muse, mutect2, varscan2
- SLC8A1 | c.604C>A p.R202S | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV60471642, COSV60489766; called by muse, mutect2, varscan2
- SLC9A2 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 66/522 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52135075; called by muse, mutect2, varscan2
- SLCO1B1 | c.1635A>C p.L545F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.043); catalogued as COSV57014217; called by muse, mutect2, varscan2
- SLITRK1 | c.549C>G p.D183E | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65676810; called by muse, mutect2, varscan2
- SMU1 | c.106G>C p.V36L | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV68140152; called by muse, mutect2, varscan2
- SOCS5 | c.393G>T p.K131N | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV100125049; called by muse, mutect2, varscan2
- SORCS1 | c.1279del p.V427Sfs*40 | Frame Shift Del (DEL) | VAF 15/113 reads (13%) | catalogued as COSV53905455; called by mutect2, pindel, varscan2
- SOX9 | c.1442C>G p.A481G | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.708); catalogued as COSV99818223; called by muse, mutect2, varscan2
- SP3 | c.484A>G p.N162D | Missense Mutation (SNP) | VAF 59/250 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV59469548; called by muse, mutect2, varscan2
- SP4 | c.1423C>A p.Q475K | Missense Mutation (SNP) | VAF 41/407 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as COSV99754119; called by muse, mutect2, varscan2
- SPATA5 | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV56780388; called by mutect2, varscan2
- SPEG | c.8501C>A p.S2834* | Nonsense Mutation (SNP) | VAF 45/221 reads (20%) | catalogued as COSV56675293; called by muse, mutect2, varscan2
- SPTA1 | c.2135C>G p.S712C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63756881; called by muse, mutect2, varscan2
- SRGAP3 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.568); catalogued as rs1407156736, COSV64530766; called by muse, mutect2, varscan2
- SRPK2 | c.1765G>T p.G589W | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61962799; called by muse, mutect2, varscan2
- STIM1 | c.1049G>T p.W350L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56157977; called by muse, mutect2, varscan2
- SULF2 | c.955G>C p.G319R | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100737126, COSV63418469; called by muse, mutect2, varscan2
- TAAR5 | c.397C>A p.H133N | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV57799499; called by muse, mutect2, varscan2
- THEMIS | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV64072754; called by muse, mutect2, varscan2
- TM4SF20 | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100459984, COSV58818830; called by muse, mutect2, varscan2
- TMEM69 | c.174G>C p.M58I | Missense Mutation (SNP) | VAF 137/797 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV63433238; called by muse, mutect2, varscan2
- TMPRSS11D | c.572C>A p.T191N | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV52224842; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1465G>T p.V489L | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as COSV100835853; called by muse, mutect2, varscan2
- TNRC18 | c.6619C>T p.Q2207* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as rs1317973015, COSV60308673; called by muse, mutect2, varscan2
- TPRG1L | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.492); catalogued as COSV60724553; called by muse, mutect2, varscan2
- TRPS1 | c.2878G>C p.A960P (on ENST00000220888 / NM_001330599.2; = p.A973P on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV55252883; called by muse, mutect2, varscan2
- TSHZ3 | c.2819G>T p.G940V | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV53677292, COSV99553158; called by muse, mutect2, varscan2
- TTC13 | c.1986G>T p.Q662H | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.804); catalogued as COSV64169226; called by muse, mutect2, varscan2
- TTN | c.76349T>C p.V25450A (on ENST00000591111; = p.V18026A on NM_003319.4) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | PolyPhen benign (0.269); catalogued as COSV60206732; called by muse, varscan2
- TTN | c.59723C>A p.T19908N (on ENST00000591111; = p.T12484N on NM_003319.4) | Missense Mutation (SNP) | VAF 81/444 reads (18%) | PolyPhen benign (0.015); catalogued as COSV60206761; called by muse, mutect2, varscan2
- UBR4 | c.10565T>G p.F3522C | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV64394901; called by muse, mutect2, varscan2
- UFC1 | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 29/182 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs1415457613, COSV63500812; called by muse, mutect2, varscan2
- UGT2B28 | c.1159G>T p.G387W | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59433381; called by muse, mutect2, varscan2
- VPS13C | c.9520C>A p.P3174T (on ENST00000644861 / NM_020821.3; = p.P3131T on NM_017684.5) | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51337026; called by muse, mutect2, varscan2
- VPS50 | c.1013G>T p.S338I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58509223; called by muse, mutect2, varscan2
- ZEB1 | c.1543A>C p.K515Q | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.922); catalogued as COSV58050033; called by muse, mutect2, varscan2
- ZFHX4 | c.5974C>T p.L1992F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1242607998, COSV51476397; called by muse, varscan2
- ZGRF1 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV52202154; called by muse, mutect2, varscan2
- ZKSCAN5 | c.451G>T p.A151S | Missense Mutation (SNP) | VAF 34/271 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100460376, COSV58743696; called by muse, mutect2, varscan2
- ZNF407 | c.3358A>T p.K1120* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV55261878; called by muse, mutect2, varscan2
- ZNF804A | c.1099A>T p.N367Y | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV56460191; called by muse, mutect2, varscan2
- C17orf78 | c.421G>C p.V141L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- FCGBP | c.6830C>A p.A2277E | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.69); called by muse, mutect2
- FRG2C | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GDF10 | c.746del p.N249Tfs*13 | Frame Shift Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, varscan2
- HDAC9 | c.2340dup p.G781Wfs*5 | Frame Shift Ins (INS) | VAF 24/186 reads (13%) | called by mutect2, pindel, varscan2
- KCNN2 | c.1262dup p.N421Kfs*54 (on ENST00000264773; = p.N633Kfs*54 on NM_021614.4) | Frame Shift Ins (INS) | VAF 6/58 reads (10%) | called by pindel, varscan2
- METTL1 | c.11_17del p.E4Gfs*34 | Frame Shift Del (DEL) | VAF 15/109 reads (14%) | called by mutect2, pindel, varscan2
- MPHOSPH9 | c.3451-1G>T p.X1151_splice | Splice Site (SNP) | VAF 17/66 reads (26%) | called by muse, mutect2
- MRC1 | c.2995C>G p.H999D | Missense Mutation (SNP) | VAF 64/414 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- MUC3A | c.8059dup p.T2687Nfs*46 | Frame Shift Ins (INS) | VAF 256/2133 reads (12%) | called by mutect2, pindel, varscan2
- POTEA | c.1391C>A p.A464E (on ENST00000519951 / NM_001005365.2; = p.A418E on NM_001002920.1) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- PRAMEF15 | c.1074T>G p.D358E | Missense Mutation (SNP) | VAF 69/535 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SUPT20HL1 | c.2630G>A p.R877K | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D3F | c.1009G>C p.D337H | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TRBV30 | c.199T>A p.S67T | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADCY2 | c.1485C>A p.T495= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV57886538; called by muse, mutect2
- AKNA | c.978G>C p.R326= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV56313963; called by muse, mutect2, varscan2
- ALPL | c.1101C>A p.S367= | Silent (SNP) | VAF 83/451 reads (18%) | catalogued as CD045924, COSV66376453; called by muse, mutect2, varscan2
- ANKRD54 | c.681T>C p.H227= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as rs1051068606, COSV99316380; called by muse, mutect2, varscan2
- ANXA2 | c.846G>A p.G282= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV60317877; called by muse, mutect2, varscan2
- ARHGEF10L | c.2811G>A p.L937= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as COSV51436915; called by muse, mutect2, varscan2
- ATP7A | c.1536G>T p.R512= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs1557232820, COSV58450416, COSV58451099; called by muse, mutect2, varscan2
- BPIFB2 | c.1131G>T p.G377= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as rs761624498, COSV50067992, COSV50070604; called by muse, mutect2, varscan2
- C6orf118 | c.141G>T p.R47= | Silent (SNP) | VAF 53/193 reads (27%) | catalogued as COSV57817086; called by muse, mutect2, varscan2
- CACNA1S | c.2019C>A p.A673= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV62941883; called by muse, mutect2, varscan2
- CBR3 | c.615G>C p.S205= | Silent (SNP) | VAF 17/97 reads (18%) | catalogued as COSV99289737; called by muse, mutect2, varscan2
- CD101 | c.1939A>C p.R647= | Silent (SNP) | VAF 58/184 reads (32%) | catalogued as COSV56719584; called by muse, mutect2, varscan2
- CDAN1 | c.846G>C p.R282= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV51168669; called by muse, mutect2, varscan2
- CEACAM16 | c.231T>A p.P77= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV101312647; called by muse, mutect2, varscan2
- CHL1 | c.618T>A p.A206= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV56599210; called by muse, mutect2, varscan2
- CSMD2 | c.6312C>A p.A2104= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV53934867, COSV53936937; called by muse, mutect2, varscan2
- CSTA | c.291C>T p.G97= | Silent (SNP) | VAF 31/154 reads (20%) | catalogued as rs370215343, COSV52612591; called by muse, mutect2, varscan2
- CYP46A1 | c.864C>T p.D288= | Silent (SNP) | VAF 30/193 reads (16%) | catalogued as rs751098169, COSV55895767; called by muse, mutect2, varscan2
- DDR2 | c.2295T>A p.T765= | Silent (SNP) | VAF 62/428 reads (14%) | catalogued as COSV63372650; called by muse, mutect2, varscan2
- DMBX1 | c.1095G>T p.R365= | Silent (SNP) | VAF 20/183 reads (11%) | catalogued as COSV100760681; called by muse, mutect2, varscan2
- DOP1B | c.3363C>T p.D1121= | Silent (SNP) | VAF 35/170 reads (21%) | catalogued as rs1303182110, COSV67694587; called by muse, mutect2, varscan2
- EDARADD | c.636C>T p.S212= (on ENST00000334232 / NM_145861.4; = p.S202= on NM_080738.4) | Silent (SNP) | VAF 47/295 reads (16%) | catalogued as COSV62063844; called by muse, mutect2, varscan2
- EREG | c.189G>A p.V63= | Silent (SNP) | VAF 34/158 reads (22%) | catalogued as COSV55262011; called by muse, mutect2, varscan2
- FAM171B | c.1369C>A p.R457= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV59006158, COSV59006503; called by muse, mutect2
- FAM234B | c.1794C>G p.T598= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV52196184; called by muse, mutect2, varscan2
- FAT2 | c.1719C>T p.I573= | Silent (SNP) | VAF 48/155 reads (31%) | catalogued as COSV55825216; called by muse, mutect2, varscan2
- FAT3 | c.1428G>T p.L476= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV53146778; called by muse, mutect2, varscan2
- FAT3 | c.12861C>G p.P4287= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV53146810, COSV99967007; called by muse, mutect2, varscan2
- FBXO36 | c.363A>T p.S121= | Silent (SNP) | VAF 38/256 reads (15%) | catalogued as COSV52279474; called by muse, mutect2, varscan2
- FKBP10 | c.552C>A p.T184= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV58637999; called by muse, mutect2, varscan2
- FLG | c.3174C>A p.V1058= | Silent (SNP) | VAF 530/1583 reads (33%) | catalogued as rs768132030, COSV64245077; called by muse, varscan2
- FRAS1 | c.4590G>A p.T1530= | Silent (SNP) | VAF 47/345 reads (14%) | catalogued as rs780780063, COSV53602161; called by muse, mutect2, varscan2
- FREM1 | c.525G>T p.L175= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as COSV101083946; called by muse, mutect2, varscan2
- FZD1 | c.1776G>T p.P592= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as COSV55312358; called by muse, mutect2, varscan2
- GPC2 | c.621G>C p.G207= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV52785817; called by muse, mutect2, varscan2
- HTR3B | c.564G>T p.L188= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as COSV52746416; called by muse, mutect2, varscan2
- HUS1B | c.261G>C p.L87= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100033180, COSV57869097; called by muse, mutect2, varscan2
- IGFBP6 | c.538C>A p.R180= | Silent (SNP) | VAF 29/157 reads (18%) | catalogued as COSV100037124, COSV56857324; called by muse, mutect2, varscan2
- IGHV1-69 | c.330G>C p.T110= | Silent (SNP) | VAF 110/425 reads (26%) | catalogued as rs370012103; called by muse, mutect2, varscan2
- IGSF9B | c.3276G>T p.P1092= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs748370176, COSV58070520; called by muse, mutect2, varscan2
- KCNH5 | c.1923C>A p.I641= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV59768828; called by muse, mutect2, varscan2
- LAMA3 | c.4437G>A p.L1479= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs775647508, COSV58074230; called by muse, mutect2, varscan2
- LRRC10 | c.435C>A p.L145= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV100825447; called by muse, mutect2, varscan2
- MMP16 | c.1665G>T p.L555= | Silent (SNP) | VAF 48/136 reads (35%) | catalogued as COSV54177807; called by muse, mutect2, varscan2
- MRC1 | c.3606A>T p.A1202= | Silent (SNP) | VAF 79/411 reads (19%) | called by muse, mutect2, varscan2
- MYH13 | c.1074G>A p.V358= | Silent (SNP) | VAF 44/171 reads (26%) | catalogued as rs762940966, COSV52836180, COSV99355345; called by muse, mutect2, varscan2
- MYT1L | c.1296C>A p.T432= | Silent (SNP) | VAF 45/220 reads (20%) | catalogued as COSV67714880, COSV67720637; called by muse, mutect2, varscan2
- NCAN | c.502C>A p.R168= | Silent (SNP) | VAF 25/156 reads (16%) | catalogued as COSV53054834; called by muse, mutect2, varscan2
- NGEF | c.318C>A p.I106= | Silent (SNP) | VAF 28/184 reads (15%) | catalogued as COSV50935929; called by muse, mutect2, varscan2
- NLRP3 | c.1345C>T p.L449= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV60228668; called by muse, mutect2, varscan2
- OBSCN | c.11373C>T p.T3791= | Silent (SNP) | VAF 38/219 reads (17%) | catalogued as COSV52802079; called by muse, mutect2, varscan2
- OR10A7 | c.324C>A p.G108= | Silent (SNP) | VAF 27/208 reads (13%) | catalogued as COSV100406512; called by muse, mutect2, varscan2
- OR2AG1 | c.711C>A p.A237= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as COSV56626678; called by muse, mutect2, varscan2
- OR4D6 | c.438G>A p.V146= | Silent (SNP) | VAF 35/280 reads (13%) | catalogued as COSV55659451; called by muse, mutect2, varscan2
- OR52N4 | c.417C>A p.T139= | Silent (SNP) | VAF 28/150 reads (19%) | catalogued as rs748092510, COSV57891956; called by muse, mutect2, varscan2
- OR56A3 | c.771C>A p.T257= | Silent (SNP) | VAF 57/294 reads (19%) | catalogued as COSV100290386, COSV61569525; called by muse, mutect2, varscan2
- OR5H2 | c.447G>T p.L149= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs769894943, COSV62351382; called by muse, mutect2, varscan2
- OR7G1 | c.441C>A p.L147= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as COSV53318320; called by muse, mutect2, varscan2
- OR9G1 | c.642G>T p.L214= | Silent (SNP) | VAF 34/322 reads (11%) | catalogued as COSV56452459; called by muse, mutect2, varscan2
- PDP1 | c.1470C>T p.N490= | Silent (SNP) | VAF 53/204 reads (26%) | catalogued as rs768875523, COSV99892022; called by muse, varscan2
- POLR1A | c.3072G>A p.L1024= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as COSV55696260; called by muse, mutect2, varscan2
- PPFIA1 | c.21G>T p.P7= | Silent (SNP) | VAF 68/393 reads (17%) | catalogued as COSV54138318; called by muse, mutect2, varscan2
- PRKG1 | c.882C>A p.V294= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs1554798558, COSV64774536, COSV64775931; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRMT8 | c.489C>A p.T163= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV54217075; called by muse, mutect2, varscan2
- PTPRC | c.216C>A p.T72= | Silent (SNP) | VAF 30/167 reads (18%) | catalogued as COSV61416821; called by muse, mutect2, varscan2
- RELN | c.6057C>T p.T2019= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV59020648; called by muse, mutect2, varscan2
- RPGRIP1 | c.1623G>A p.E541= | Silent (SNP) | VAF 8/53 reads (15%) | catalogued as rs1303176340, COSV99250579; called by mutect2, varscan2
- SCN3A | c.2625T>A p.I875= | Silent (SNP) | VAF 28/139 reads (20%) | catalogued as COSV51817525; called by muse, mutect2, varscan2
- SHQ1 | c.399C>G p.P133= | Silent (SNP) | VAF 41/199 reads (21%) | catalogued as rs376103451, COSV57764649; called by muse, mutect2, varscan2
- SLC44A3 | c.1950C>T p.A650= (on ENST00000271227 / NM_001114106.3; = p.A602= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as rs1400980315, COSV54732360; called by muse, mutect2
- SLITRK1 | c.1332G>T p.A444= | Silent (SNP) | VAF 53/231 reads (23%) | catalogued as COSV65676806; called by muse, mutect2, varscan2
- SSU72P8 | c.399T>A p.P133= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV66361265; called by muse, mutect2, varscan2
- TMEM132D | c.1917C>A p.T639= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV101243092, COSV67161427; called by muse, mutect2, varscan2
- TMEM63C | c.1236A>T p.A412= | Silent (SNP) | VAF 26/164 reads (16%) | catalogued as COSV53606153; called by muse, mutect2, varscan2
- TRIM60 | c.519A>G p.K173= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV61971215; called by muse, mutect2, varscan2
- TRPC6 | c.1467C>A p.S489= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV100723766, COSV60258228; called by muse, mutect2, varscan2
- TRPM2 | c.2748C>A p.I916= | Silent (SNP) | VAF 92/470 reads (20%) | catalogued as COSV55973433; called by muse, mutect2, varscan2
- ZFHX4 | c.7170C>A p.P2390= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as COSV51476441, COSV99259529; called by muse, mutect2
- ZNF143 | c.1401G>T p.G467= | Silent (SNP) | VAF 54/270 reads (20%) | catalogued as COSV55181266; called by muse, varscan2
- ZNF208 | c.444C>A p.G148= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs749859394, COSV68110024; called by muse, mutect2, varscan2
- ZNF385D | c.291C>A p.A97= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV55765990; called by muse, mutect2, varscan2
- ZNF536 | c.3633C>T p.P1211= | Silent (SNP) | VAF 19/161 reads (12%) | catalogued as COSV62829421; called by muse, mutect2, varscan2
- MASP1 | c.1303+5739G>T | Intron (SNP) | VAF 9/143 reads (6%) | catalogued as COSV56225551; called by muse, mutect2
- NEK7 | c.198+3186G>C | Intron (SNP) | VAF 4/29 reads (14%) | catalogued as COSV100954374, COSV66312939; called by muse, mutect2, varscan2
- SSPOP | n.952T>A | RNA (SNP) | VAF 43/278 reads (15%) | catalogued as COSV50488498; called by muse, mutect2, varscan2
- TMEM183B | n.815C>T | RNA (SNP) | VAF 77/487 reads (16%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1106G>C | 3'UTR (SNP) | VAF 2/19 reads (11%) | catalogued as COSV99739378, COSV99749621; called by muse, mutect2
